Somatic mutation profile of tumor specimen MMRF_2440_1_BM_CD138pos (aliquot MMRF_2440_1_BM_CD138pos_T1_KHS5U_L11237) from MMRF case MMRF_2440, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 47.1 years (17,208 days).
Specimen MMRF_2440_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0e6d2642-ef49-459a-97f2-60de4541cc33.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2440_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2440_1_PB_Whole_C3_KHS5U_L11238; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8fa696df-248f-46fc-96c4-0b2604c5057a

The open-access MAF lists 66 somatic variants for this specimen: 25 protein-altering or splice-affecting, 6 silent, 35 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 23, Missense Mutation 23, Silent 6, Intron 4, 3'Flank 3, 5'Flank 3, 5'UTR 2, Frame Shift Ins 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1901A>G p.D634G (on ENST00000288602 / NM_001374244.1; = p.D594G on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.369); catalogued as rs121913338, COSV56065695, COSV56224199, COSV56283955; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- KRAS | c.34G>C p.G12R | Missense Mutation (SNP) | VAF 80/184 reads (43%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.497); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CSPG5 | c.188C>T p.A63V | Missense Mutation (SNP) | VAF 3/51 reads (6%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.007); catalogued as rs1223546701; called by muse, mutect2
- IGHV1-69D | c.46G>C p.G16R | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.619); catalogued as rs1237605917; called by mutect2, varscan2
- IGHV2-70 | c.109C>T p.L37F | Missense Mutation (SNP) | VAF 44/77 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs368945949; called by muse, varscan2
- KCNK4 | c.5G>A p.R2H | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.072); catalogued as rs867555217, COSV100487267; called by muse, mutect2, varscan2
- LRFN2 | c.509G>A p.R170Q | Missense Mutation (SNP) | VAF 14/159 reads (9%) | SIFT tolerated (0.98); PolyPhen benign (0.121); catalogued as rs759803528, COSV57823733; called by muse, mutect2
- MUC3A | c.1016C>A p.S339Y | Missense Mutation (SNP) | VAF 98/186 reads (53%) | SIFT deleterious, low confidence (0); catalogued as rs934973062; called by muse, mutect2
- NFIB | c.241C>T p.R81C | Missense Mutation (SNP) | VAF 41/165 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); catalogued as COSV66620793; called by muse, mutect2, varscan2
- NOS2 | c.902G>A p.R301H | Missense Mutation (SNP) | VAF 51/120 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); catalogued as rs200678947; called by muse, mutect2, varscan2
- PAMR1 | c.607C>T p.R203W | Missense Mutation (SNP) | VAF 56/138 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs776344621; called by muse, mutect2, varscan2
- PGAP6 | c.1843G>T p.G615W | Missense Mutation (SNP) | VAF 56/117 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV51741352; called by muse, mutect2, varscan2
- PRR5 | c.752G>A p.R251H (on ENST00000336985 / NM_181333.4; = p.R242H on NM_015366.4) | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as rs753229319; called by muse, mutect2
- RYR1 | c.820C>T p.R274C | Missense Mutation (SNP) | VAF 34/99 reads (34%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.993); catalogued as rs770370125, COSV62102805; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TMEM132C | c.712C>T p.R238* | Nonsense Mutation (SNP) | VAF 84/174 reads (48%) | catalogued as rs1398496122; called by muse, mutect2, varscan2
- BIRC3 | c.1492dup p.T498Nfs*21 | Frame Shift Ins (INS) | VAF 18/57 reads (32%) | called by mutect2, pindel, varscan2
- CACNA1E | c.5540C>A p.S1847Y | Missense Mutation (SNP) | VAF 26/65 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- DSCAM | c.5919G>C p.Q1973H | Missense Mutation (SNP) | VAF 46/243 reads (19%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0); called by muse, mutect2, varscan2
- GRK2 | c.1879G>T p.G627W | Missense Mutation (SNP) | VAF 144/527 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- LRRIQ1 | c.1316T>C p.L439P | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT tolerated (0.17); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MLXIP | c.2381T>G p.I794S | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- OR9A4 | c.368A>G p.Y123C | Missense Mutation (SNP) | VAF 5/136 reads (4%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.627); called by muse, mutect2
- PCDH1 | c.1918G>C p.D640H | Missense Mutation (SNP) | VAF 64/240 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- VAV3 | c.1355T>C p.I452T | Missense Mutation (SNP) | VAF 20/39 reads (51%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.67); called by muse, mutect2, varscan2
- VCPIP1 | c.1346A>C p.Q449P | Missense Mutation (SNP) | VAF 107/244 reads (44%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- ADAM17 | c.1998G>A p.K666= | Silent (SNP) | VAF 18/42 reads (43%) | called by muse, mutect2, varscan2
- CDH6 | c.1098T>C p.D366= | Silent (SNP) | VAF 61/173 reads (35%) | called by muse, mutect2, varscan2
- DOCK1 | c.3804G>A p.T1268= | Silent (SNP) | VAF 34/74 reads (46%) | catalogued as rs1288379916, COSV99733772; called by muse, mutect2, varscan2
- IGHV2-70 | c.96A>G p.K32= | Silent (SNP) | VAF 30/72 reads (42%) | catalogued as rs368957766; called by muse, varscan2
- INSYN2A | c.858C>T p.D286= | Silent (SNP) | VAF 29/63 reads (46%) | catalogued as rs764156865, COSV54741060; called by muse, mutect2, varscan2
- TRIML1 | c.120C>T p.L40= | Silent (SNP) | VAF 55/102 reads (54%) | catalogued as COSV60195960; called by muse, mutect2, varscan2
- ACVR2A | c.*584A>G | 3'UTR (SNP) | VAF 30/61 reads (49%) | called by muse, mutect2, varscan2
- ANKH | c.*4422C>G | 3'UTR (SNP) | VAF 18/63 reads (29%) | called by muse, mutect2, varscan2
- ASIC1 | c.*1562G>A | 3'UTR (SNP) | VAF 36/65 reads (55%) | called by muse, mutect2, varscan2
- CCDC60 | c.*150C>A | 3'UTR (SNP) | VAF 101/194 reads (52%) | called by muse, mutect2, varscan2
- CFAP69 | c.*497G>T | 3'UTR (SNP) | VAF 49/100 reads (49%) | called by muse, mutect2, varscan2
- DGKB | c.*2279A>G | 3'UTR (SNP) | VAF 29/53 reads (55%) | catalogued as COSV51785053; called by muse, mutect2, varscan2
- DHX33 | c.*1464T>C | 3'UTR (SNP) | VAF 28/65 reads (43%) | called by muse, mutect2, varscan2
- DNAI4 | c.*447T>G | 3'UTR (SNP) | VAF 5/9 reads (56%) | called by muse, mutect2, varscan2
- EPHA7 | c.*300T>G | 3'UTR (SNP) | VAF 16/56 reads (29%) | catalogued as rs1292009531; called by muse, mutect2, varscan2
- FASTKD2 | c.*63G>T | 3'UTR (SNP) | VAF 6/25 reads (24%) | called by muse, mutect2, varscan2
- FCAMR | c.1455-12C>T | Intron (SNP) | VAF 3/50 reads (6%) | called by muse, mutect2
- FCRL5 | c.1681+1140A>G | Intron (SNP) | VAF 26/70 reads (37%) | called by muse, mutect2, varscan2
- FMN2 | c.*263G>A | 3'UTR (SNP) | VAF 32/76 reads (42%) | called by muse, mutect2, varscan2
- GNAL | chr18:11883461 A>G | 3'Flank (SNP) | VAF 25/71 reads (35%) | catalogued as rs1001622923; called by muse, mutect2, varscan2
- HERC2P3 | chr15:20457613 C>A | 5'Flank (SNP) | VAF 8/106 reads (8%) | called by muse, mutect2
- HSD17B12 | c.*391C>T | 3'UTR (SNP) | VAF 14/58 reads (24%) | called by muse, mutect2, varscan2
- LMO2 | c.-151G>A | 5'UTR (SNP) | VAF 60/95 reads (63%) | called by muse, mutect2, varscan2
- MAML2 | c.*1118A>T | 3'UTR (SNP) | VAF 70/97 reads (72%) | called by muse, mutect2, varscan2
- NANP | chr20:25624098 C>A | 5'Flank (SNP) | VAF 46/116 reads (40%) | catalogued as rs1251834165; called by muse, mutect2, varscan2
- NDUFV1 | chr11:67604919 A>C | 5'Flank (SNP) | VAF 59/203 reads (29%) | called by muse, mutect2, varscan2
- NKIRAS2 | c.*1244C>T | 3'UTR (SNP) | VAF 34/66 reads (52%) | called by muse, mutect2, varscan2
- OOSP2 | c.243+35T>G | Intron (SNP) | VAF 35/127 reads (28%) | called by muse, mutect2, varscan2
- OSBPL8 | c.*3991A>C | 3'UTR (SNP) | VAF 23/40 reads (58%) | catalogued as rs951691343; called by muse, mutect2, varscan2
- PPP2R3A | c.1996-3737G>A | Intron (SNP) | VAF 191/431 reads (44%) | catalogued as rs753998062, COSV53861097; called by muse, mutect2, varscan2
- PRKAB1 | c.*12C>T | 3'UTR (SNP) | VAF 16/41 reads (39%) | catalogued as rs372902331; called by muse, mutect2, varscan2
- SLAMF7 | c.*60_*61del | 3'UTR (DEL) | VAF 76/241 reads (32%) | called by mutect2, pindel, varscan2
- SLC6A5 | c.*1650del | 3'UTR (DEL) | VAF 58/102 reads (57%) | catalogued as rs896617242; called by mutect2, varscan2
- SNTG1 | chr8:50793497 T>A | 3'Flank (SNP) | VAF 44/92 reads (48%) | called by muse, mutect2, varscan2
- SPECC1 | chr17:20315255 G>A | 3'Flank (SNP) | VAF 28/65 reads (43%) | called by muse, mutect2, varscan2
- TBL1XR1 | c.*5239_*5243del | 3'UTR (DEL) | VAF 17/46 reads (37%) | called by mutect2, pindel, varscan2
- TECRL | c.-48T>C | 5'UTR (SNP) | VAF 110/256 reads (43%) | called by muse, mutect2, varscan2
- TMEM154 | c.*5920A>G | 3'UTR (SNP) | VAF 3/47 reads (6%) | called by muse, mutect2
- TXNDC15 | c.*271T>A | 3'UTR (SNP) | VAF 53/178 reads (30%) | called by muse, mutect2, varscan2
- UGT8 | c.*490G>A | 3'UTR (SNP) | VAF 19/54 reads (35%) | called by muse, mutect2
- ZBTB6 | c.*2378T>C | 3'UTR (SNP) | VAF 39/149 reads (26%) | called by muse, mutect2, varscan2
